Somatic mutation profile of tumor specimen TCGA-CR-7395-01A (aliquot TCGA-CR-7395-01A-11D-2012-08) from TCGA case TCGA-CR-7395, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 80.8 years (29,527 days).
Specimen TCGA-CR-7395-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0cc22a08-1c4d-4341-a789-f3d8113bfb16.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-7395-10A (Blood Derived Normal), aliquot TCGA-CR-7395-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce7d00b9-9d3a-495c-941e-55fd5284ddbf

The open-access MAF lists 158 somatic variants for this specimen: 110 protein-altering or splice-affecting, 47 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 47, Nonsense Mutation 8, Frame Shift Ins 5, Frame Shift Del 3, Splice Site 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SERPINA1 | c.1158dup p.E387Rfs*14 | Frame Shift Ins (INS) | VAF 13/60 reads (22%) | catalogued as rs764325655; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- TTN | c.43360C>T p.R14454* (on ENST00000591111; = p.R7030* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 41/170 reads (24%) | catalogued as rs374140736, CM133385; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC6 | c.722G>A p.R241K | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99228174; called by muse, mutect2
- ADCY4 | c.1573C>T p.R525C | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as rs368960669; called by muse, mutect2, varscan2
- ADGRA1 | c.994G>A p.D332N | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV101192646; called by muse, mutect2, varscan2
- ARID2 | c.1498+1G>A p.X500_splice | Splice Site (SNP) | VAF 14/96 reads (15%) | catalogued as COSV57618245; called by muse, mutect2, varscan2
- ARID2 | c.5029C>T p.R1677* | Nonsense Mutation (SNP) | VAF 9/117 reads (8%) | catalogued as rs1368075571, COSV57614810; called by muse, mutect2
- ATM | c.1236G>C p.W412C | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CS145383, COSV99069698, COSV99587703; called by muse, mutect2, varscan2
- BCS1L | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs372817977; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BTK | c.1797G>C p.E599D | Missense Mutation (SNP) | VAF 18/197 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV100437341; called by muse, mutect2, varscan2
- C4orf19 | c.806C>T p.S269L | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as rs367961468; called by muse, mutect2
- CACHD1 | c.3026A>G p.D1009G | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.243); catalogued as COSV99261557; called by muse, mutect2, varscan2
- CCDC40 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as rs770369678, COSV99481380; called by mutect2, varscan2
- CCT4 | c.1208G>A p.R403H | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101075072; called by muse, mutect2, varscan2
- CEP63 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.115); catalogued as COSV100132593; called by muse, mutect2, varscan2
- CPXM2 | c.1076C>T p.S359L | Missense Mutation (SNP) | VAF 38/306 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99581230; called by muse, mutect2, varscan2
- DCP1B | c.1147A>C p.N383H | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV99767284; called by muse, mutect2, varscan2
- DDAH1 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.796); catalogued as rs756689761, COSV52303391; called by muse, mutect2, varscan2
- DNAH17 | c.2494G>A p.V832I | Missense Mutation (SNP) | VAF 32/244 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV101101586; called by muse, mutect2, varscan2
- DNAJC1 | c.1216T>G p.L406V | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as COSV100981102; called by muse, mutect2, varscan2
- DNMT3A | c.1463G>A p.R488Q | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs566390868, COSV53057506, COSV99259907; called by muse, mutect2, varscan2
- DSG1 | c.930C>G p.I310M | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV99935622; called by muse, mutect2, varscan2
- EP300 | c.4780-1G>A p.X1594_splice | Splice Site (SNP) | VAF 10/204 reads (5%) | catalogued as COSV99607544; called by muse, mutect2
- EXD1 | c.1259A>T p.E420V | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.425); catalogued as COSV100153504; called by muse, mutect2, varscan2
- EXD1 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.005); catalogued as COSV100153506; called by muse, mutect2, varscan2
- FAM83G | c.2372C>T p.S791F | Missense Mutation (SNP) | VAF 27/189 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100524850; called by muse, mutect2, varscan2
- FANCG | c.1810G>A p.D604N | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV100734111; called by muse, mutect2, varscan2
- FAT1 | c.2173C>T p.Q725* | Nonsense Mutation (SNP) | VAF 9/57 reads (16%) | catalogued as COSV71675113; called by muse, mutect2, varscan2
- FRYL | c.6122G>A p.R2041Q | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as rs764312788, COSV51940848, COSV51952315; called by muse, mutect2, varscan2
- GREB1 | c.3601G>A p.D1201N | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.226); catalogued as rs368897613; called by muse, varscan2
- GRM2 | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.605); catalogued as rs759390511, COSV56584825; called by muse, mutect2, varscan2
- HECTD4 | c.3477G>A p.M1159I | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1382687326, COSV100295857; called by muse, mutect2, varscan2
- HNRNPA1L2 | c.493C>G p.Q165E | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV100676463; called by muse, mutect2, varscan2
- HS3ST2 | c.759C>G p.Y253* | Nonsense Mutation (SNP) | VAF 14/158 reads (9%) | catalogued as COSV54461980, COSV54465941, COSV99757704; called by muse, mutect2
- HTR1E | c.325T>C p.S109P | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100540974; called by muse, mutect2, varscan2
- HYDIN | c.5452C>A p.Q1818K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99992114; called by muse, mutect2, varscan2
- IGHA2 | c.701C>T p.T234M | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs782717196; called by mutect2, varscan2
- INTS6L | c.1094T>G p.L365R | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV100878030; called by muse, mutect2
- JMJD1C | c.3617C>T p.A1206V | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100550182; called by muse, mutect2, varscan2
- KAAG1 | c.79C>T p.Q27* | Nonsense Mutation (SNP) | VAF 11/86 reads (13%) | catalogued as COSV99219686; called by muse, mutect2, varscan2
- KCTD1 | c.103G>C p.D35H | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100517512; called by muse, mutect2
- KIAA0753 | c.2818G>C p.G940R | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.859); catalogued as COSV100810537; called by muse, mutect2
- KRT27 | c.1356G>C p.K452N | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.357); catalogued as COSV100053179; called by muse, mutect2, varscan2
- LIPA | c.221C>G p.S74C | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as COSV99259924; called by muse, mutect2, varscan2
- LRP2 | c.8764G>A p.E2922K | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.109); catalogued as rs370790771; called by muse, mutect2, varscan2
- LRRN3 | c.1036C>T p.L346F | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100068316; called by muse, mutect2, varscan2
- MAP3K19 | c.1619C>T p.S540L | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs748308749, COSV100208155, COSV100208162; called by mutect2, varscan2
- MAPK9 | c.484G>C p.D162H | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.307); catalogued as COSV100558157; called by muse, mutect2
- MARCHF4 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV99814106; called by muse, mutect2, varscan2
- MICU1 | c.263A>C p.K88T | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV100741651; called by muse, mutect2
- MIGA1 | c.1141G>C p.D381H | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100889748, COSV100889788; called by muse, varscan2
- MTMR8 | c.1228A>T p.M410L | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.042); catalogued as COSV100878322; called by muse, mutect2
- MYBPC1 | c.2563G>A p.E855K (on ENST00000550270 / NM_206820.2; = p.E862K on NM_002465.4) | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100637773; called by muse, mutect2, varscan2
- MYO3A | c.2177A>C p.K726T | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.925); catalogued as COSV99778570; called by muse, mutect2, varscan2
- NCBP1 | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.02); catalogued as COSV100910607; called by muse, mutect2, varscan2
- NCBP3 | c.897G>A p.W299* | Nonsense Mutation (SNP) | VAF 8/95 reads (8%) | catalogued as COSV99339309; called by muse, mutect2
- NECTIN3 | c.359G>A p.R120K | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.323); catalogued as COSV100162153, COSV60550212; called by muse, mutect2, varscan2
- NHLRC1 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61481288; called by muse, mutect2, varscan2
- NOB1 | c.103A>G p.T35A | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs1421005354, COSV99263867; called by muse, mutect2, varscan2
- NOTCH1 | c.6191C>T p.P2064L | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV53043143; called by muse, mutect2
- NOX1 | c.1686A>C p.E562D | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99471451; called by muse, mutect2
- NPAP1 | c.2536G>A p.E846K | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT tolerated (0.78); PolyPhen benign (0.065); catalogued as COSV100274858; called by muse, mutect2, varscan2
- OR10H4 | c.460T>G p.S154A | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.669); catalogued as COSV100437682; called by muse, mutect2, varscan2
- OR4K5 | c.322A>C p.T108P | Missense Mutation (SNP) | VAF 19/266 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV100262175; called by muse, mutect2
- OR51A2 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as rs1187550515, COSV100985001; called by muse, mutect2, varscan2
- OR5H14 | c.293A>T p.K98M | Missense Mutation (SNP) | VAF 29/226 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101454086, COSV71194076; called by muse, mutect2, varscan2
- OR8H1 | c.71A>C p.Q24P | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV100476869; called by muse, mutect2
- OR8J3 | c.592A>G p.I198V | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100040584; called by muse, mutect2, varscan2
- OSBP2 | c.1493C>T p.S498L | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs374035667; called by muse, mutect2
- PAPOLA | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as COSV99353947; called by muse, mutect2, varscan2
- PARP4 | c.1909G>A p.A637T | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101131307; called by muse, mutect2, varscan2
- PCDHA1 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.207); catalogued as COSV100974279, COSV100974326; called by muse, mutect2, varscan2
- PCDHGB3 | c.1888C>T p.R630C | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99532221; called by muse, mutect2, varscan2
- PHIP | c.3685C>T p.R1229* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | catalogued as COSV99243504; called by muse, mutect2, varscan2
- PLEKHA3 | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.059); catalogued as COSV52296570; called by muse, mutect2, varscan2
- PLXNA3 | c.3817G>A p.E1273K | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.304); catalogued as COSV100859824; called by muse, mutect2, varscan2
- PLXNA3 | c.3964-1G>A p.X1322_splice | Splice Site (SNP) | VAF 7/98 reads (7%) | catalogued as COSV100859825; called by muse, mutect2
- PMPCA | c.1312A>T p.N438Y | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100867722; called by muse, mutect2, varscan2
- PTCH1 | c.3886G>A p.G1296R | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated, low confidence (0.68); PolyPhen possibly damaging (0.616); catalogued as rs372828014, COSV59464956; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTH2R | c.691T>C p.S231P | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.082); catalogued as COSV99782143; called by muse, mutect2
- SERINC5 | c.245G>A p.C82Y | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101549056; called by muse, mutect2, varscan2
- SLIT2 | c.3772G>T p.G1258C | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99881472, COSV99888190; called by muse, mutect2, varscan2
- SOBP | c.2460G>T p.M820I | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.136); catalogued as COSV100432837; called by muse, mutect2, varscan2
- SOX13 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV99689869; called by muse, mutect2
- SPSB3 | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.325); catalogued as COSV99236363; called by muse, mutect2
- SRSF7 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.958); catalogued as COSV100492542; called by mutect2, varscan2
- STAMBPL1 | c.211T>A p.L71M | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100905079; called by muse, mutect2, varscan2
- STRADB | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.452); catalogued as COSV99524317; called by muse, mutect2, varscan2
- SUPT3H | c.280C>T p.L94F (on ENST00000371460 / NM_181356.3; = p.L83F on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.046); catalogued as COSV100176304; called by muse, mutect2
- SYDE2 | c.1477T>A p.L493M | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.694); catalogued as COSV99320261; called by muse, mutect2, varscan2
- SYNJ2 | c.3836C>T p.T1279I | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.07); catalogued as COSV100840042; called by muse, mutect2, varscan2
- TAF1 | c.2351G>A p.R784Q (on ENST00000373790 / NM_138923.4; = p.R805Q on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52108636; called by muse, mutect2
- TBC1D4 | c.1669G>A p.D557N | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV100884533, COSV66487639; called by muse, mutect2, varscan2
- WDR13 | c.511G>A p.V171M | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.687); catalogued as rs1448378505, COSV99489137; called by muse, mutect2, varscan2
- ZBTB41 | c.2663G>A p.G888E | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100962883; called by muse, mutect2, varscan2
- ZNF440 | c.1318C>T p.Q440* | Nonsense Mutation (SNP) | VAF 8/62 reads (13%) | catalogued as COSV58370491, COSV58372642; called by muse, mutect2, varscan2
- ZNF585B | c.1376T>G p.I459S | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100459324; called by muse, mutect2
- ZSCAN31 | c.1119C>G p.H373Q | Missense Mutation (SNP) | VAF 25/263 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100716902; called by muse, mutect2
- ACO1 | c.1063T>G p.F355V | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- CASP8 | c.235dup p.L79Pfs*4 | Frame Shift Ins (INS) | VAF 11/58 reads (19%) | called by mutect2, pindel, varscan2
- CPNE2 | c.910_913del p.C304Sfs*8 | Frame Shift Del (DEL) | VAF 8/88 reads (9%) | called by mutect2, pindel
- DST | c.3796_3797del p.Q1266Ifs*3 (on ENST00000361203 / NM_001374722.1; = p.Q940Ifs*3 on NM_001723.6) | Frame Shift Del (DEL) | VAF 10/107 reads (9%) | called by mutect2, varscan2
- FOXD4L4 | c.974C>T p.S325L | Missense Mutation (SNP) | VAF 28/355 reads (8%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.069); called by muse, mutect2
- GALNT6 | c.1378G>T p.G460C | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HLA-B | c.646dup p.H216Pfs*5 | Frame Shift Ins (INS) | VAF 23/184 reads (13%) | called by mutect2, varscan2
- ITGB3BP | c.187_188del p.K63Efs*11 | Frame Shift Del (DEL) | VAF 7/47 reads (15%) | called by mutect2, pindel
- NSD2 | c.335dup p.N113* | Frame Shift Ins (INS) | VAF 6/54 reads (11%) | called by mutect2, pindel, varscan2
- NSG1 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- RNF122 | c.264dup p.Y89Ifs*17 | Frame Shift Ins (INS) | VAF 43/320 reads (13%) | called by mutect2, pindel, varscan2
- AGPAT1 | c.474C>T p.V158= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as COSV100421553; called by muse, mutect2
- AGPAT5 | c.21C>G p.L7= | Silent (SNP) | VAF 3/27 reads (11%) | catalogued as COSV99576299; called by muse, mutect2
- AGXT2 | c.393C>T p.L131= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as rs758853262, COSV51485327; called by muse, mutect2, varscan2
- AKAP1 | c.207C>T p.S69= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV100027742; called by muse, mutect2, varscan2
- CAP2 | c.1245G>A p.K415= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV100012164; called by muse, mutect2, varscan2
- CCDC9B | c.486G>A p.V162= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as rs772371096, COSV101233477; called by muse, mutect2, varscan2
- CDH20 | c.1953C>A p.I651= | Silent (SNP) | VAF 13/131 reads (10%) | catalogued as COSV99404528; called by muse, mutect2, varscan2
- CRAT | c.657T>C p.S219= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100539837; called by mutect2, varscan2
- CX3CR1 | c.495C>T p.F165= | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as COSV64195218; called by muse, mutect2, varscan2
- DHX38 | c.1914C>T p.L638= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as COSV51700505; called by muse, mutect2
- DOP1A | c.2673G>A p.Q891= | Silent (SNP) | VAF 5/95 reads (5%) | catalogued as COSV99381114; called by muse, mutect2
- F8 | c.6264T>G p.S2088= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV100811295; called by muse, mutect2, varscan2
- GABRB3 | c.909C>G p.V303= | Silent (SNP) | VAF 16/119 reads (13%) | catalogued as COSV100158468, COSV54656702; called by muse, mutect2, varscan2
- GLI2 | c.4674C>T p.L1558= (on ENST00000361492 / NM_001374353.1; = p.L1575= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/123 reads (12%) | catalogued as rs769916555, COSV100082481; called by muse, mutect2, varscan2
- GPR151 | c.285A>G p.R95= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as COSV99694470; called by muse, mutect2, varscan2
- GUCY1A1 | c.111A>G p.S37= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV99637241; called by muse, mutect2, varscan2
- HMCN1 | c.7218G>A p.L2406= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as rs1422771545, COSV54891866, COSV99623515, COSV99624932; called by muse, mutect2, varscan2
- IL27RA | c.1452C>A p.P484= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV99651979; called by mutect2, varscan2
- ISM1 | c.1323C>T p.N441= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as rs748892925, COSV52607711; called by muse, mutect2, varscan2
- KIAA1549 | c.2241T>C p.A747= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV99649951; called by muse, mutect2, varscan2
- MAN2A2 | c.204C>T p.I68= | Silent (SNP) | VAF 12/124 reads (10%) | catalogued as COSV100847768; called by muse, mutect2, varscan2
- NCOR1 | c.2202C>T p.S734= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as rs755394382, COSV99247907; called by muse, mutect2, varscan2
- NFASC | c.1302G>A p.S434= (on ENST00000339876 / NM_001378329.1; = p.S445= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs750856686, COSV58361811; called by mutect2, varscan2
- NHLRC1 | c.921G>A p.V307= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as COSV61481704; called by muse, mutect2, varscan2
- NMB | c.72C>T p.V24= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV100850539; called by muse, mutect2, varscan2
- NUP155 | c.1932T>G p.T644= (on ENST00000231498 / NM_153485.3; = p.T585= on NM_004298.4) | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV99192269; called by muse, mutect2, varscan2
- OR1C1 | c.351G>T p.V117= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV101376189, COSV68715967; called by muse, mutect2, varscan2
- OR4L1 | c.867G>A p.L289= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as COSV100235582; called by muse, mutect2, varscan2
- OR5H15 | c.123G>C p.G41= | Silent (SNP) | VAF 26/325 reads (8%) | catalogued as COSV100736618; called by muse, varscan2
- PAH | c.219G>A p.K73= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as COSV100187699; called by muse, mutect2, varscan2
- PHLPP2 | c.3141C>T p.L1047= | Silent (SNP) | VAF 20/180 reads (11%) | catalogued as COSV100673538; called by muse, varscan2
- PLCG2 | c.1128G>A p.R376= | Silent (SNP) | VAF 18/124 reads (15%) | catalogued as rs753644315, COSV100842083; called by muse, mutect2
- PNPLA3 | c.1194G>A p.L398= | Silent (SNP) | VAF 17/109 reads (16%) | catalogued as COSV99336958; called by muse, mutect2, varscan2
- POLR3E | c.288G>A p.L96= | Silent (SNP) | VAF 45/365 reads (12%) | catalogued as COSV100241942; called by muse, mutect2, varscan2
- POU6F1 | c.1788C>T p.R596= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as COSV100374729; called by muse, mutect2, varscan2
- SH3D21 | c.1170C>T p.L390= (on ENST00000453908 / NM_001162530.2; = p.L279= on NM_024676.5) | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV99583928; called by muse, mutect2, varscan2
- SIGLEC12 | c.1299G>T p.L433= (on ENST00000291707 / NM_053003.4; = p.L315= on NM_033329.2) | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV52460539, COSV99389115; called by muse, mutect2, varscan2
- SLC1A7 | c.273C>T p.L91= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs776184320, COSV65194936; called by muse, mutect2, varscan2
- SLC38A10 | c.1425G>A p.P475= | Silent (SNP) | VAF 15/152 reads (10%) | catalogued as rs771978613, COSV99917215; called by muse, mutect2
- SOX14 | c.315C>G p.L105= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as rs781687358, COSV60163192; called by muse, mutect2, varscan2
- SRCAP | c.1905G>A p.K635= | Silent (SNP) | VAF 12/113 reads (11%) | catalogued as rs886051900, COSV99349435; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- STAG3 | c.969C>T p.I323= | Silent (SNP) | VAF 32/402 reads (8%) | catalogued as COSV100425673; called by muse, mutect2, varscan2
- TTLL11 | c.1128C>T p.C376= | Silent (SNP) | VAF 14/123 reads (11%) | catalogued as COSV100388471; called by muse, mutect2, varscan2
- UQCC2 | c.135C>T p.T45= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV100951968; called by muse, mutect2, varscan2
- USP9X | c.3843C>T p.D1281= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as rs768506015, COSV100198569; called by muse, mutect2, varscan2
- WDR70 | c.1056G>A p.Q352= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV54271263, COSV99457765; called by muse, mutect2, varscan2
- XIRP1 | c.574A>C p.R192= | Silent (SNP) | VAF 7/87 reads (8%) | catalogued as COSV100453427; called by muse, mutect2
- PPP4R4 | c.295-3258C>T | Intron (SNP) | VAF 5/41 reads (12%) | catalogued as COSV58558315; called by muse, mutect2, varscan2
